TCGA case TCGA-12-0778 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/db5ea0e6-4cac-4f18-8643-32afb1e0287d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Dead; Days to death: 454 days (1.2 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 53.3 years (19,460 days); Year of diagnosis: 2006; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 68 days; Treatment dose: 5,940 cGy; Number of fractions: 34; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 68 days; Number of cycles: 1; Treatment dose: 75 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 89 days; Days to treatment end: 147 days; Number of cycles: 2; Treatment dose: 200 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 147 days; Days to treatment end: 232 days; Number of cycles: 2; Treatment dose: 110 mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 239 days; Days to treatment end: 258 days; Treatment dose: 3,500 cGy; Number of fractions: 19; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 250 days; Days to treatment end: 329 days; Treatment dose: 10 mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 250 days; Days to treatment end: 329 days; Number of cycles: 3; Treatment dose: 50 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide + Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 329 days; Days to treatment end: 352 days; Number of cycles: 1; Treatment dose: 50 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 355 days; Days to treatment end: 385 days (1.1 years); Treatment dose: 200 mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sirolimus; Initial disease status: Progressive Disease; Days to treatment start: 355 days; Days to treatment end: 385 days (1.1 years); Treatment dose: 150 mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sirolimus; Initial disease status: Progressive Disease; Days to treatment start: 355 days; Days to treatment end: 385 days (1.1 years); Treatment dose: 15 mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 363 days; Days to treatment end: 363 days; Treatment dose: 1,800 cGy; Number of fractions: 1; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 363 days; Days to treatment end: 363 days; Treatment dose: 1,500 cGy; Number of fractions: 1; Treatment anatomic sites: Locoregional Site.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 53.9 years (19,692 days); Days to diagnosis: 232 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (4 entries)
- Day 232 (post initial treatment): Progression or recurrence: Yes; Days to progression: 232 days.
- Days to follow up: 452 days (1.2 years); Disease response: With Tumor.
- Days to follow up: 454 days (1.2 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-0778-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-12-0778-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-12-0778-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0.
- Sample TCGA-12-0778-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-0778-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Temozolamide.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 3: Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 4: Pharmaceutical therapy drug name: Avastin.
- Drug treatment 4, Route of administrations: Route of administration: IV.
- Drug treatment 5: Pharmaceutical therapy drug name: Tarceva.
- Drug treatment 7: Pharmaceutical therapy drug name: Rapamcyin.
- Drug treatment 8: Pharmaceutical therapy drug name: VP-16.
- Drug treatment 10: Pharmaceutical therapy drug name: Rapamycin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 454 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 454 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 232 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-0778-01A-01D-0333-01): tumor purity 0.63, ploidy 2.21, whole-genome doublings 0.
